Somatic mutation profile of tumor specimen 3b044c9b-ac09-4b4b-8f37-462411 (aliquot 3b044c9b-ac09-4b4b-8f37-462411_D6) from CPTAC case 02OV036, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB.
Specimen 3b044c9b-ac09-4b4b-8f37-462411: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ddbf3e7-68e2-41d7-b83d-1e1871d22759.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 936e1c41-7756-465c-b292-29d4a0 (Blood Derived Normal), aliquot 936e1c41-7756-465c-b292-29d4a0_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e47163b1-6a94-447f-bac1-759017346e6b

The open-access MAF lists 58 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 15, Intron 5, Nonsense Mutation 4, Frame Shift Del 3, 5'UTR 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 170/206 reads (83%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- BBX | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168225341, COSV57880212, COSV57881518, COSV57884048; called by muse, mutect2, varscan2
- CASS4 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 42/384 reads (11%) | catalogued as COSV64388074; called by muse, mutect2, varscan2
- ENPP2 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs748334064; called by muse, mutect2, varscan2
- ENPP4 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs748776505, COSV58089310; called by muse, mutect2
- GOLIM4 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370361838, COSV58329325; called by muse, mutect2, varscan2
- KIF26B | c.4409C>T p.S1470L | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1254298903; called by muse, mutect2, varscan2
- KIFC2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1205240190; called by muse, mutect2, varscan2
- LAPTM4B | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as rs773880261; called by muse, mutect2
- NPAT | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs199837111; called by muse, mutect2, varscan2
- OPRK1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as rs767220566, COSV99654565; called by muse, mutect2, varscan2
- OR3A3 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 227/314 reads (72%) | catalogued as rs375267220; called by muse, mutect2, varscan2
- OTOA | c.3458G>T p.W1153L (on ENST00000286149; = p.W1139L on NM_144672.4) | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs893362230, COSV99624143; called by muse, mutect2, varscan2
- PCDHGB2 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 109/626 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs757133043, COSV54032053; called by muse, mutect2
- SDK2 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs776859124; called by muse, mutect2, varscan2
- ABTB2 | c.866G>T p.C289F | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ARHGAP21 | c.2584T>C p.S862P | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC102A | c.1270G>C p.V424L | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CUBN | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GET3 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.196); called by muse, mutect2
- GGT7 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HIBCH | c.750+2T>C p.X250_splice | Splice Site (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- HNRNPA2B1 | c.104A>T p.E35V (on ENST00000354667 / NM_031243.3; = p.E23V on NM_002137.4) | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- INPP5J | c.2758C>G p.L920V (on ENST00000331075 / NM_001284285.2; = p.L552V on NM_001002837.2) | Missense Mutation (SNP) | VAF 126/502 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAB21L2 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 83/606 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MYO10 | c.862T>A p.Y288N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OXR1 | c.2137G>A p.E713K (on ENST00000442977 / NM_001198532.1; = p.E685K on NM_018002.3) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PVALB | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RANBP6 | c.493_503del p.H165Dfs*9 | Frame Shift Del (DEL) | VAF 41/203 reads (20%) | called by mutect2, pindel, varscan2
- SCN10A | c.3085del p.Q1029Sfs*15 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel
- SGSM2 | c.441C>A p.Y147* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- SORCS1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SPINDOC | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2
- UBL7 | c.1115del p.E372Gfs*? | Frame Shift Del (DEL) | VAF 25/166 reads (15%) | called by mutect2, pindel, varscan2
- UBR4 | c.14751dup p.G4918Rfs*12 | Frame Shift Ins (INS) | VAF 33/199 reads (17%) | called by mutect2, pindel, varscan2
- WDR33 | c.753C>G p.D251E | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACACA | c.7095C>T p.P2365= | Silent (SNP) | VAF 42/494 reads (9%) | called by muse, mutect2
- ARHGAP15 | c.691A>C p.R231= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV54494366; called by muse, mutect2, varscan2
- ARHGEF2 | c.315C>T p.P105= | Silent (SNP) | VAF 33/232 reads (14%) | catalogued as rs752167938; called by muse, mutect2, varscan2
- DLL4 | c.1593C>T p.A531= | Silent (SNP) | VAF 170/371 reads (46%) | catalogued as rs544067517, COSV51068095; called by muse, mutect2, varscan2
- GPATCH8 | c.432A>G p.Q144= | Silent (SNP) | VAF 36/222 reads (16%) | catalogued as rs1230193143; called by muse, mutect2, varscan2
- H2AC21 | c.27C>T p.G9= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- HELZ2 | c.4047C>T p.G1349= (on ENST00000467148 / NM_001037335.2; = p.G780= on NM_033405.3) | Silent (SNP) | VAF 184/540 reads (34%) | catalogued as rs747817298, COSV71296969; called by muse, mutect2, varscan2
- IL17D | c.426C>T p.V142= | Silent (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- MAPK10 | c.513A>C p.G171= (on ENST00000359221 / NM_001351625.2; = p.G209= on NM_002753.5) | Silent (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- PHF3 | c.5868C>T p.D1956= | Silent (SNP) | VAF 30/255 reads (12%) | called by muse, varscan2
- PPFIA3 | c.1293C>T p.S431= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs755095884, COSV61949440; called by muse, mutect2, varscan2
- PWWP3A | c.1245A>G p.L415= (on ENST00000627377; = p.L414= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV60903596; called by muse, mutect2, varscan2
- SEPTIN9 | c.1351C>T p.L451= (on ENST00000427177 / NM_001113491.2; = p.L433= on NM_006640.4) | Silent (SNP) | VAF 45/253 reads (18%) | catalogued as rs1337562359; called by muse, mutect2, varscan2
- SPACA1 | c.18G>A p.T6= | Silent (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- TESK1 | c.450G>A p.P150= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as rs774204273, COSV99427297, COSV99427380; called by muse, mutect2, varscan2
- C1orf159 | c.-48C>T | 5'UTR (SNP) | VAF 33/151 reads (22%) | catalogued as rs535856868; called by muse, mutect2, varscan2
- CRELD1 | c.-30T>A | 5'UTR (SNP) | VAF 43/225 reads (19%) | called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2828G>A | Intron (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- NEB | c.16314+758G>A | Intron (SNP) | VAF 16/130 reads (12%) | catalogued as rs1042514269; called by muse, mutect2, varscan2
- NICN1 | c.495+66A>C | Intron (SNP) | VAF 38/148 reads (26%) | called by muse, mutect2, varscan2
- R3HDM2 | c.1303-2552G>A | Intron (SNP) | VAF 10/78 reads (13%) | catalogued as rs986194496, COSV61285196; called by muse, mutect2, varscan2
- SLC22A25 | c.1071-1780T>C | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
